Somatic mutation profile of tumor specimen TCGA-UT-A88D-01B (aliquot TCGA-UT-A88D-01B-11D-A39R-32) from TCGA case TCGA-UT-A88D, project TCGA-MESO (Mesothelioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Epithelioid mesothelioma, malignant; Tissue or organ of origin: Pleura, NOS; AJCC pathologic stage: Stage II; Age at diagnosis: 66.5 years (24,300 days).
Specimen TCGA-UT-A88D-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3136c3cd-c159-4d9a-b5fa-f4e6da7b2f8f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-UT-A88D-10A (Blood Derived Normal), aliquot TCGA-UT-A88D-10A-01D-A39U-32; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/32d0b852-b46b-4604-a657-b1650f1cc8f8

The open-access MAF lists 28 somatic variants for this specimen: 22 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 18, Silent 6, Nonsense Mutation 2, Frame Shift Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC2 | c.728C>T p.A243V | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.431); catalogued as rs375179902; called by muse, mutect2, varscan2
- C5orf24 | c.401A>G p.Y134C | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs775285368; called by muse, mutect2, varscan2
- CD79B | c.8G>A p.R3K | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.69); PolyPhen benign (0.037); catalogued as rs1387440194; called by muse, mutect2, varscan2
- CDCP1 | c.1840C>T p.R614W | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.648); catalogued as rs1262291486, COSV56104487; called by muse, mutect2, varscan2
- DTWD1 | c.109C>T p.Q37* | Nonsense Mutation (SNP) | VAF 4/40 reads (10%) | catalogued as COSV52072395; called by muse, mutect2
- KLHL3 | c.1501C>T p.P501S | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.097); catalogued as CM120741; called by muse, mutect2, varscan2
- PIWIL3 | c.934G>A p.E312K | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.535); catalogued as COSV100177659; called by muse, mutect2, varscan2
- PTPN14 | c.2524G>T p.E842* | Nonsense Mutation (SNP) | VAF 14/86 reads (16%) | catalogued as COSV65283047; called by muse, mutect2
- SEC23IP | c.413C>G p.S138W | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.797); catalogued as COSV64831564; called by muse, mutect2, varscan2
- SLC9A3R1 | c.774del p.F259Sfs*28 | Frame Shift Del (DEL) | VAF 14/97 reads (14%) | catalogued as COSV99379860; called by mutect2, pindel, varscan2
- TSPOAP1 | c.884C>T p.P295L | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs1248191464; called by muse, mutect2, varscan2
- USH2A | c.96G>C p.E32D | Missense Mutation (SNP) | VAF 24/123 reads (20%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as COSV56340536; called by muse, mutect2, varscan2
- WSCD2 | c.635G>A p.R212H | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs774410691, COSV54589448; called by muse, mutect2, varscan2
- ZNF835 | c.1322C>T p.T441M | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV73379267, COSV73379700; called by muse, mutect2, varscan2
- ALKAL1 | c.104C>T p.A35V | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.003); called by muse, varscan2
- BAP1 | c.752del p.N251Tfs*6 | Frame Shift Del (DEL) | VAF 45/159 reads (28%) | called by mutect2, pindel, varscan2
- CFAP70 | c.1301C>A p.P434H | Missense Mutation (SNP) | VAF 22/144 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.669); called by muse, mutect2, varscan2
- DOCK6 | c.3167C>T p.T1056I | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ITFG2 | c.1286T>A p.L429H | Missense Mutation (SNP) | VAF 28/152 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); called by muse, mutect2, varscan2
- OPLAH | c.3376G>A p.A1126T | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRIM8 | c.164G>A p.C55Y | Missense Mutation (SNP) | VAF 36/165 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- VPS13D | c.5054A>T p.Y1685F | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- ALKAL1 | c.46C>T p.L16= | Silent (SNP) | VAF 9/44 reads (20%) | called by muse, varscan2
- C10orf71 | c.219C>T p.G73= | Silent (SNP) | VAF 20/70 reads (29%) | called by muse, mutect2, varscan2
- GRIN2A | c.231C>A p.T77= | Silent (SNP) | VAF 28/142 reads (20%) | catalogued as rs1483174642, COSV58032505; called by muse, mutect2, varscan2
- KRT78 | c.1020G>A p.Q340= | Silent (SNP) | VAF 5/69 reads (7%) | called by muse, mutect2
- NFIA | c.654C>T p.V218= | Silent (SNP) | VAF 17/106 reads (16%) | called by muse, mutect2, varscan2
- PREP | c.1803C>T p.S601= (on ENST00000369110; = p.S667= on NM_002726.5) | Silent (SNP) | VAF 18/79 reads (23%) | called by muse, mutect2, varscan2
